Somatic mutation profile of tumor specimen TCGA-B4-5843-01A (aliquot TCGA-B4-5843-01A-11D-1669-08) from TCGA case TCGA-B4-5843, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 45.9 years (16,779 days).
Specimen TCGA-B4-5843-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3828cbbe-6d43-44c9-a971-324a18519ff0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B4-5843-10A (Blood Derived Normal), aliquot TCGA-B4-5843-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72f360f1-b3e3-4cad-be42-714772cd5030

The open-access MAF lists 40 somatic variants for this specimen: 34 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 5, Frame Shift Del 4, Frame Shift Ins 2, Splice Region 1, Splice Site 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN4 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1031037100, COSV53142731; called by muse, mutect2, varscan2
- ADAMTSL2 | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63203159; called by muse, mutect2, varscan2
- ADCY4 | c.1981G>A p.G661R | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.411); catalogued as COSV60251779, COSV60251890; called by muse, mutect2, varscan2
- ADGRB2 | c.1373del p.G458Vfs*62 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | catalogued as COSV57077671; called by mutect2, pindel, varscan2
- AKAP9 | c.2061T>A p.N687K | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.144); catalogued as COSV62338215; called by muse, mutect2, varscan2
- ARHGDIG | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51982989; called by muse, mutect2
- BOD1L1 | c.6187G>A p.G2063R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as COSV50006371; called by muse, mutect2, varscan2
- CAVIN4 | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.661); catalogued as COSV56866487, COSV56867445; called by muse, mutect2, varscan2
- CCDC81 | c.1412A>T p.K471I (on ENST00000445632 / NM_001156474.2; = p.K381I on NM_021827.4) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV53576439; called by muse, mutect2, varscan2
- CLK3 | c.1876G>A p.E626K (on ENST00000395066 / NM_001130028.1; = p.E478K on NM_003992.4) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV59338936; called by muse, mutect2, varscan2
- DMXL1 | c.8276-1G>T p.X2759_splice | Splice Site (SNP) | VAF 37/117 reads (32%) | catalogued as COSV60704356; called by muse, mutect2, varscan2
- DNAJC10 | c.490T>A p.L164I | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51135699; called by muse, mutect2, varscan2
- HNRNPK | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as COSV61088164; called by muse, mutect2, varscan2
- KIAA0100 | c.1071G>C p.K357N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV66490409; called by muse, mutect2, varscan2
- MED25 | c.1457T>C p.L486P | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57202827; called by muse, mutect2
- NCOR1 | c.356T>A p.F119Y | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV51959820; called by muse, mutect2, varscan2
- NUMA1 | c.4123G>A p.A1375T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as COSV61183018; called by muse, mutect2, varscan2
- RBM28 | c.525C>A p.N175K | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148752295, COSV56161549; called by muse, mutect2, varscan2
- RPAP2 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV72509131; called by muse, mutect2, varscan2
- RUSC1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.175); catalogued as COSV52738062; called by muse, mutect2, varscan2
- SBF1 | c.941T>C p.I314T | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV62365423; called by muse, mutect2, varscan2
- SCYL3 | c.106T>C p.F36L | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV63044374; called by muse, mutect2, varscan2
- SNW1 | c.71C>A p.A24E | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.76); PolyPhen benign (0.017); catalogued as COSV55052955; called by muse, mutect2, varscan2
- TBXA2R | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64343076; called by muse, mutect2, varscan2
- TGFBR3 | c.738T>C p.S246= | Splice Region (SNP) | VAF 9/64 reads (14%) | catalogued as COSV53021350; called by muse, mutect2, varscan2
- TROAP | c.942del p.L315Cfs*26 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | catalogued as rs766897414; called by mutect2, pindel, varscan2
- UGT2B28 | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 100/271 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV59430448; called by muse, mutect2, varscan2
- VSIG8 | c.514G>C p.G172R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63652246; called by muse, mutect2, varscan2
- ZNF485 | c.1284T>G p.H428Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV62423533; called by muse, mutect2, varscan2
- CCDC181 | c.1451del p.A484Vfs*31 (on ENST00000367806 / NM_001300969.1; = p.A483Vfs*31 on NM_021179.2) | Frame Shift Del (DEL) | VAF 27/131 reads (21%) | called by mutect2, pindel, varscan2
- ELN | c.846_854del p.V285_G287del | In Frame Del (DEL) | VAF 33/79 reads (42%) | called by mutect2, pindel, varscan2
- HS6ST1 | c.752dup p.R252Afs*70 | Frame Shift Ins (INS) | VAF 26/50 reads (52%) | called by mutect2, varscan2
- HS6ST1 | c.751delinsCT p.V251Lfs*71 | Frame Shift Ins (INS) | VAF 38/107 reads (36%) | called by pindel, varscan2*
- STAG1 | c.3437_3440del p.F1146Yfs*11 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- CLC | c.147C>T p.D49= | Silent (SNP) | VAF 70/178 reads (39%) | catalogued as rs1398998483, COSV55684674; called by muse, mutect2, varscan2
- LMTK2 | c.3405C>G p.P1135= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV51989945; called by muse, mutect2, varscan2
- SPOCD1 | c.1362C>T p.S454= | Silent (SNP) | VAF 52/167 reads (31%) | catalogued as COSV57093588; called by muse, mutect2, varscan2
- TNC | c.5343C>T p.A1781= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as COSV60780049; called by muse, mutect2, varscan2
- TXNDC2 | c.1332C>T p.F444= (on ENST00000306084 / NM_001098529.2; = p.F377= on NM_032243.6) | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1489151398, COSV60151712; called by muse, mutect2, varscan2
- IKBIP | c.297+8077C>T | Intron (SNP) | VAF 26/145 reads (18%) | catalogued as COSV100141693; called by muse, mutect2, varscan2
